Gene-level copy-number profile of tumor specimen TCGA-AX-A05Y-01A from TCGA case TCGA-AX-A05Y, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 57.2 years (20,904 days).
Specimen TCGA-AX-A05Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.19a46451-57c1-4d2c-8154-50a110ce28eb.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A05Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 363 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e668e0d1-e301-482c-b228-657315496bc3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 528; copy number 2: 1,405; copy number 3: 55,212; copy number 4: 2,595.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A05Y-01A-11D-A00X-01): tumor purity 0.98, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 528. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
